CPTAC case 11BR060 — Breast — Ductal and Lobular Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/efd0c8b6-ae7c-44cd-81fd-aaba58d83c2f

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.8 years (19,284 days); AJCC pathologic stage: Stage IIB; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 23d5da6f-7593-4652-8db6-07372e: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample 97cc4d46-cf80-41f1-b99c-bc4829: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
